Gene-level copy-number profile of tumor specimen TCGA-CV-7103-01A from TCGA case TCGA-CV-7103, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.9 years (18,219 days).
Specimen TCGA-CV-7103-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6ecd61db-f545-4831-a67c-dd6f3914b308.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7103-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c1a07a97-2813-4922-a68d-01d708ad3ec4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 2: 14,569; copy number 3: 2,590; copy number 4: 36,734; copy number 5: 1,340; copy number 6: 2,549; copy number 7: 108; copy number 8: 776; copy number 9: 939; copy number 10: 34; copy number 11: 13; copy number 12: 37; copy number 28: 37; copy number 34: 15; copy number 41: 30; copy number 56: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7103-01A-21D-2010-01): tumor purity 0.67, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:67,577,624–68,331,613, 9 genes (within-gene range 0–2): AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,140 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:202,634,969–203,226,378, 13 genes, copy number 11 (within-gene range 2–11): FAM117B, ICA1L, AC098831.1, KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36.
- chr3:171,058,414–186,493,661, 263 genes, copy number 9–56 (within-gene range 8–56) (broad region; genes not listed).
- chr7:38,256,337–38,335,514, 14 genes, copy number 9: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
